Somatic mutation profile of tumor specimen TCGA-MI-A75G-01A (aliquot TCGA-MI-A75G-01A-11D-A32G-10) from TCGA case TCGA-MI-A75G, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 63.7 years (23,284 days).
Specimen TCGA-MI-A75G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af21d80e-af05-4137-922c-527c5112caff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MI-A75G-10A (Blood Derived Normal), aliquot TCGA-MI-A75G-10A-01D-A32G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db55b6dc-b0c4-420b-9cf6-0428be211b17

The open-access MAF lists 251 somatic variants for this specimen: 197 protein-altering or splice-affecting, 49 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 164, Silent 49, Frame Shift Del 13, Nonsense Mutation 10, Frame Shift Ins 5, Intron 3, Splice Site 3, Nonstop Mutation 1, Splice Region 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRYGD | c.402C>A p.Y134* | Nonsense Mutation (SNP) | VAF 45/93 reads (48%) | catalogued as rs398122948, CM074129, COSV52205208, COSV52205350; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.836A>G p.Y279C | Missense Mutation (SNP) | VAF 117/269 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs121918456, CM021133, CM041069, COSV61009292; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 78/97 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC3 | c.422G>T p.W141L | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as rs745705296, COSV53322542; called by muse, mutect2, varscan2
- ABCC3 | c.423G>T p.W141C | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV53322563; called by muse, mutect2, varscan2
- AC004922.1 | c.1400A>G p.K467R | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.752); catalogued as COSV53163412; called by muse, mutect2, varscan2
- AC008397.2 | c.2098C>G p.P700A | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); catalogued as COSV53207171; called by muse, mutect2, varscan2
- ADAM19 | c.979G>A p.G327R | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57430721; called by muse, mutect2, varscan2
- ADAMTS18 | c.3479G>A p.C1160Y | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51412886; called by muse, mutect2, varscan2
- ADARB1 | c.1649G>A p.R550Q (on ENST00000360697 / NM_001346687.2; = p.R510Q on NM_001112.4) | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.934); catalogued as rs1409743479, COSV62344580; called by muse, mutect2, varscan2
- ADCY2 | c.1283C>A p.S428Y | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV57860306, COSV57874595; called by muse, mutect2, varscan2
- ALB | c.1681C>T p.P561S | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55738496; called by muse, mutect2, varscan2
- ALS2CL | c.14A>T p.E5V | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as COSV59671629; called by muse, mutect2, varscan2
- ARAP1 | c.2073C>A p.F691L (on ENST00000393609 / NM_001040118.2; = p.F446L on NM_015242.4) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.053); catalogued as COSV61991374; called by muse, mutect2
- ARHGAP15 | c.584C>T p.S195L | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV54494546, COSV54497758; called by muse, mutect2, varscan2
- ASTN1 | c.2431G>T p.V811F | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as COSV56070378; called by muse, mutect2, varscan2
- ATP8A1 | c.1325G>A p.C442Y | Missense Mutation (SNP) | VAF 68/318 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52535997; called by muse, mutect2, varscan2
- ATR | c.5381-1G>T p.X1794_splice | Splice Site (SNP) | VAF 40/136 reads (29%) | catalogued as COSV63386901, COSV63393542; called by muse, mutect2, varscan2
- BOD1L1 | c.3614A>G p.K1205R | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV50014729, COSV99238336; called by muse, mutect2, varscan2
- BRSK2 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV57543578; called by muse, mutect2, varscan2
- BTBD16 | c.1061A>T p.Q354L | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV53263343; called by muse, mutect2, varscan2
- BTN1A1 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 85/195 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.658); catalogued as COSV55067846; called by muse, mutect2, varscan2
- BYSL | c.14A>T p.K5M | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV54825203; called by muse, mutect2, varscan2
- C11orf71 | c.46A>T p.R16W | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.085); catalogued as COSV57784392; called by muse, mutect2, varscan2
- C3orf20 | c.994A>G p.T332A | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.086); catalogued as COSV53785704; called by muse, mutect2, varscan2
- C5orf22 | c.589T>G p.S197A | Missense Mutation (SNP) | VAF 55/173 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.138); catalogued as COSV57598589; called by muse, mutect2, varscan2
- CCL8 | c.133A>G p.I45V | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as COSV67013988; called by muse, mutect2, varscan2
- CCPG1 | c.2138A>T p.E713V | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV51241930; called by muse, mutect2, varscan2
- CCR1 | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56122288; called by muse, mutect2, varscan2
- CCR3 | c.930G>T p.K310N | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as COSV62463618; called by muse, mutect2, varscan2
- CCT3 | c.413A>G p.K138R | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV55289307; called by muse, mutect2, varscan2
- CDC40 | c.1120A>T p.K374* | Nonsense Mutation (SNP) | VAF 16/110 reads (15%) | catalogued as COSV57009725; called by muse, mutect2, varscan2
- CDKL4 | c.693C>A p.N231K | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66509722; called by muse, mutect2, varscan2
- CELSR3 | c.6509G>T p.W2170L | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV50866038; called by muse, mutect2, varscan2
- CFAP206 | c.1098G>T p.M366I | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV51534457; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.580G>T p.A194S | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.869); catalogued as COSV51592085; called by muse, mutect2, varscan2
- CHD9 | c.4269G>A p.W1423* | Nonsense Mutation (SNP) | VAF 16/59 reads (27%) | catalogued as COSV54610865; called by muse, mutect2, varscan2
- CHSY3 | c.2075A>T p.K692M | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.102); catalogued as COSV59277967; called by muse, mutect2
- CNRIP1 | c.83A>G p.D28G | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as rs1214903582, COSV55148745; called by muse, mutect2, varscan2
- CNTN5 | c.536T>A p.V179E | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as COSV54314480; called by muse, mutect2, varscan2
- COLGALT2 | c.1477T>A p.Y493N | Missense Mutation (SNP) | VAF 59/315 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62299429; called by muse, varscan2
- CREBBP | c.973A>T p.M325L | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.092); catalogued as rs747990896, COSV52125067; called by muse, mutect2, varscan2
- CRLF2 | c.105C>G p.I35M | Missense Mutation (SNP) | VAF 64/437 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1465167956, COSV67493755; called by muse, mutect2, varscan2
- CTH | c.179A>G p.Y60C | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61008608; called by muse, mutect2, varscan2
- CTHRC1 | c.131A>G p.Q44R | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as CM116250, COSV57715028, COSV57715635; called by muse, mutect2, varscan2
- CTSB | c.461A>G p.Y154C | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV61540755; called by muse, mutect2, varscan2
- CUBN | c.702G>A p.M234I | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV64716648; called by muse, mutect2, varscan2
- DCD | c.97C>A p.P33T | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.231); catalogued as COSV53201684; called by muse, mutect2, varscan2
- DDI1 | c.703C>A p.P235T | Missense Mutation (SNP) | VAF 55/97 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56379437; called by muse, mutect2, varscan2
- DEF6 | c.1356A>C p.E452D | Missense Mutation (SNP) | VAF 62/155 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57354165; called by muse, mutect2, varscan2
- DFFB | c.209T>G p.V70G | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV58214951; called by muse, mutect2, varscan2
- DHX57 | c.1918A>G p.R640G | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54885690; called by muse, mutect2, varscan2
- DIS3L | c.2518A>G p.I840V (on ENST00000319212 / NM_001143688.3; = p.I757V on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.135); catalogued as COSV59912479; called by muse, mutect2, varscan2
- DSPP | c.1314C>A p.H438Q | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.743); catalogued as COSV56810773; called by muse, mutect2, varscan2
- EDNRA | c.485C>A p.P162H | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV60097848; called by muse, mutect2, varscan2
- EFCAB14 | c.1444G>A p.G482R | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.074); catalogued as rs1294733356, COSV61906163; called by muse, mutect2, varscan2
- ELAVL2 | c.365T>C p.I122T | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV99807330; called by muse, mutect2
- EPB42 | c.568G>T p.D190Y (on ENST00000441366 / NM_001114134.2; = p.D220Y on NM_000119.3) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55749926; called by muse, mutect2, varscan2
- ERBIN | c.3806A>G p.N1269S (on ENST00000284037 / NM_001253697.2; = p.N1228S on NM_018695.4) | Missense Mutation (SNP) | VAF 67/213 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV52317315; called by muse, varscan2
- ESS2 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.007); catalogued as COSV50082394; called by muse, mutect2, varscan2
- EYA1 | c.632C>T p.S211L | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as rs757772659, CM044880, COSV58163776; called by muse, mutect2, varscan2
- FAM171B | c.2431A>G p.T811A | Missense Mutation (SNP) | VAF 96/229 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.906); catalogued as COSV59003953; called by muse, mutect2, varscan2
- FAM189A2 | c.826G>T p.D276Y | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV57384825; called by muse, mutect2, varscan2
- FAM237A | c.76T>G p.C26G | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.882); catalogued as COSV101405602; called by muse, mutect2
- FASTKD2 | c.784A>G p.I262V | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.152); catalogued as rs1447569233, COSV52698632; called by muse, mutect2, varscan2
- FBN2 | c.2814T>C p.D938= | Splice Region (SNP) | VAF 7/67 reads (10%) | catalogued as COSV52515884; called by muse, mutect2, varscan2
- FBXO24 | c.765G>T p.E255D (on ENST00000241071 / NM_033506.3; = p.E293D on NM_012172.5) | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV53826354; called by muse, mutect2
- FBXO38 | c.909C>G p.C303W | Missense Mutation (SNP) | VAF 52/188 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57028140; called by muse, mutect2, varscan2
- FCGBP | c.10792C>T p.R3598C | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs1419034147; called by muse, mutect2
- FILIP1L | c.3248C>A p.P1083H (on ENST00000354552 / NM_182909.3; = p.P843H on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/212 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.07); catalogued as COSV100497407; called by muse, mutect2, varscan2
- FPGT | c.1331G>A p.G444E | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as COSV63840635; called by muse, mutect2, varscan2
- FUT1 | c.1042G>T p.E348* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as CM970544, COSV59568429; called by muse, mutect2, varscan2
- GABRG3 | c.253G>T p.V85L | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.1); catalogued as COSV61519292; called by muse, mutect2, varscan2
- GALNT3 | c.17G>T p.R6L | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); catalogued as COSV67061818; called by muse, mutect2
- GATAD2A | c.1532G>T p.R511L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV53066374, COSV53070500; called by muse, mutect2
- GCN1 | c.3161G>A p.R1054H | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as rs201424442; called by muse, mutect2, varscan2
- GIMAP6 | c.34G>T p.E12* | Nonsense Mutation (SNP) | VAF 10/91 reads (11%) | catalogued as COSV61033506, COSV61033550; called by muse, mutect2, varscan2
- GOLGB1 | c.6286G>T p.A2096S | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV61466234; called by muse, mutect2, varscan2
- H1-2 | c.278T>C p.L93P | Missense Mutation (SNP) | VAF 56/123 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV59190913; called by muse, mutect2, varscan2
- HELZ | c.2540G>A p.R847Q | Missense Mutation (SNP) | VAF 52/80 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62378699; called by muse, mutect2, varscan2
- HERC2 | c.9193G>T p.D3065Y | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55325395; called by muse, mutect2, varscan2
- HGF | c.664C>A p.L222I | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV55950199; called by muse, mutect2, varscan2
- HHATL | c.1133T>A p.L378Q | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99825804; called by muse, mutect2, varscan2
- HHATL | c.1132C>A p.L378M | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV99825805; called by muse, mutect2, varscan2
- HNRNPH2 | c.1030G>T p.A344S | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV57266174; called by muse, mutect2, varscan2
- IGKV3-7 | c.155G>T p.S52I | Missense Mutation (SNP) | VAF 91/202 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as rs369120313; called by muse, mutect2, varscan2
- IL18 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs768324029, COSV54781579; called by muse, mutect2, varscan2
- IPO13 | c.1111A>T p.I371F | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV64894400; called by muse, mutect2, varscan2
- ITGB4 | c.2849T>A p.I950N | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV99564865; called by muse, mutect2, varscan2
- ITGB4 | c.2850C>G p.I950M | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV99564867; called by muse, mutect2, varscan2
- KCTD16 | c.410G>A p.S137N | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV72579028; called by muse, mutect2, varscan2
- KLHDC9 | c.26G>T p.R9L | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); catalogued as COSV63509688; called by mutect2, varscan2
- KRT83 | c.101C>A p.A34D | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99531931; called by muse, mutect2, varscan2
- LAMA2 | c.2314G>A p.E772K | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.438); catalogued as COSV70348115, COSV70351947; called by muse, mutect2, varscan2
- LAMC2 | c.3314T>A p.L1105H | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs901074396, COSV51455941; called by muse, mutect2
- LRP1 | c.1609A>G p.I537V | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV54512779; called by muse, mutect2, varscan2
- LRRC47 | c.498C>G p.D166E | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.86); PolyPhen benign (0.096); catalogued as COSV65562579; called by muse, mutect2, varscan2
- LTF | c.1745C>A p.A582D | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV51608374; called by muse, mutect2, varscan2
- MAGEA11 | c.1136C>T p.P379L | Missense Mutation (SNP) | VAF 58/110 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV60755845, COSV60759205; called by muse, mutect2, varscan2
- MAN2A2 | c.1121G>T p.R374L | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64637813, COSV64638413; called by muse, mutect2, varscan2
- MARS1 | c.615G>T p.Q205H | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV56255120; called by muse, mutect2, varscan2
- MCM7 | c.1123A>G p.I375V | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.674); catalogued as COSV57996717; called by muse, mutect2, varscan2
- MEP1A | c.427A>G p.I143V | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs1374101638, COSV57920299; called by muse, mutect2, varscan2
- METTL27 | c.106G>T p.A36S | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52895938; called by muse, mutect2
- MMP9 | c.1566C>A p.D522E | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63434130; called by muse, mutect2
- MOGAT3 | c.901C>T p.L301F | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.596); catalogued as COSV56174698; called by muse, mutect2, varscan2
- MRPL51 | c.100A>G p.I34V | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1310948707, COSV57519775; called by muse, mutect2, varscan2
- MTMR7 | c.270C>A p.C90* | Nonsense Mutation (SNP) | VAF 34/100 reads (34%) | catalogued as rs368887856; called by muse, mutect2, varscan2
- MUC16 | c.16120G>T p.V5374L | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as COSV67468961; called by muse, mutect2
- MUC16 | c.16118T>G p.L5373R | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV67468964; called by muse, mutect2
- MYO7B | c.3697A>T p.S1233C | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as COSV67348120; called by muse, mutect2, varscan2
- NLRP9 | c.2765G>C p.W922S | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as COSV60463576; called by muse, mutect2, varscan2
- NR2F2 | c.403C>A p.R135S | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67683525; called by muse, mutect2, varscan2
- NT5C2 | c.125C>G p.A42G | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.825); catalogued as COSV58416541; called by muse, mutect2, varscan2
- OPLAH | c.2699C>A p.A900D | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as rs186909122, COSV70679053; called by muse, mutect2
- OR2T1 | c.208A>G p.M70V | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV63542033; called by muse, mutect2, varscan2
- OR2T27 | c.217T>C p.Y73H | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as COSV100788420; called by muse, mutect2, varscan2
- OR4C15 | c.794C>G p.S265C (on ENST00000314644; = p.S211C on NM_001001920.2) | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.067); catalogued as COSV58951070, COSV58953111; called by muse, mutect2, varscan2
- OTOGL | c.6604G>C p.V2202L (on ENST00000547103; = p.V2193L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.056); catalogued as COSV100087735, COSV54017287; called by muse, mutect2, varscan2
- PALD1 | c.251G>T p.R84L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54973973; called by muse, mutect2, varscan2
- PARP12 | c.1666G>T p.A556S | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.022); catalogued as COSV54934528; called by muse, mutect2, varscan2
- PCDH11Y | c.1784A>G p.Q595R (on ENST00000400457 / NM_032973.2; = p.Q584R on NM_032971.3) | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.715); catalogued as COSV53081567; called by muse, mutect2, varscan2
- PCDH9 | c.1610G>A p.R537Q | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.913); catalogued as COSV60531552; called by muse, mutect2, varscan2
- PCSK5 | c.4895C>A p.A1632E | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.668); catalogued as rs1223721563, COSV101377409, COSV70450027; called by muse, mutect2, varscan2
- PDE11A | c.1750C>T p.H584Y | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53695831; called by muse, mutect2, varscan2
- PDE1B | c.448T>C p.Y150H | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV54493132; called by muse, mutect2, varscan2
- PLCB4 | c.296G>C p.C99S | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.966); catalogued as COSV53803171, COSV53819964; called by muse, mutect2, varscan2
- PLCE1 | c.2858T>C p.I953T | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV53352165; called by muse, mutect2, varscan2
- PLEK | c.478T>A p.C160S | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52251993; called by muse, mutect2, varscan2
- PLPP2 | c.32A>G p.D11G | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV54120799; called by muse, mutect2, varscan2
- PPP1R13B | c.2785G>A p.V929I | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs773911225, COSV52451890; called by muse, mutect2, varscan2
- PRKDC | c.4798A>G p.M1600V | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as rs1201974576, COSV58053267; called by muse, mutect2, varscan2
- PROSER1 | c.878A>G p.N293S | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as COSV61487598; called by muse, mutect2, varscan2
- PSG3 | c.480G>T p.E160D | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV59504511, COSV59505373; called by muse, mutect2, varscan2
- PTPRM | c.302A>T p.Y101F | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV59860918; called by muse, mutect2, varscan2
- RAD51 | c.321A>T p.K107N | Missense Mutation (SNP) | VAF 99/318 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV51111780; called by muse, mutect2, varscan2
- RALGAPB | c.3629G>A p.G1210D | Missense Mutation (SNP) | VAF 28/205 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53438200; called by muse, mutect2, varscan2
- REPS1 | c.758A>G p.Q253R | Missense Mutation (SNP) | VAF 63/101 reads (62%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV57811144; called by muse, mutect2, varscan2
- RGN | c.394G>T p.G132W | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60276244; called by muse, mutect2, varscan2
- RIF1 | c.6281C>T p.S2094F | Missense Mutation (SNP) | VAF 74/149 reads (50%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV54617611; called by muse, mutect2, varscan2
- RMND1 | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 55/365 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60550687; called by muse, mutect2, varscan2
- ROBO2 | c.1392A>T p.R464S | Missense Mutation (SNP) | VAF 12/171 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as COSV59913323; called by muse, mutect2
- RPGRIP1 | c.503G>A p.R168K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV52847435; called by muse, mutect2, varscan2
- SAG | c.65G>T p.R22L | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.64); catalogued as rs371502229, COSV68591185; called by muse, mutect2, varscan2
- SALL2 | c.2761C>A p.P921T | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as COSV58103604; called by muse, mutect2, varscan2
- SAMD5 | c.195G>C p.Q65H | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); catalogued as COSV100822577; called by muse, mutect2
- SCLY | c.1360T>C p.*454Qext*26 (on ENST00000651534; = p.*446Qext*26 on NM_016510.7) | Nonstop Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as rs1436291474, COSV54541481; called by muse, mutect2
- SFT2D2 | c.271A>T p.K91* | Nonsense Mutation (SNP) | VAF 110/196 reads (56%) | catalogued as COSV54799243; called by muse, mutect2, varscan2
- SIGLECL1 | c.419A>G p.H140R | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as rs1269710984, COSV57063043; called by muse, mutect2, varscan2
- SLC24A1 | c.795A>T p.E265D | Missense Mutation (SNP) | VAF 50/165 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as COSV56051958; called by muse, mutect2, varscan2
- SLC26A4 | c.568A>G p.S190G | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.012); catalogued as COSV55916983; called by muse, mutect2, varscan2
- SLC2A5 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 23/68 reads (34%) | catalogued as COSV66236835; called by muse, mutect2, varscan2
- SLC2A5 | c.186G>T p.M62I | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.023); catalogued as COSV66236848, COSV66237992; called by muse, mutect2, varscan2
- SLC38A3 | c.1264G>T p.V422F | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68844027; called by muse, mutect2, varscan2
- SLC4A8 | c.1525-1G>T p.X509_splice | Splice Site (SNP) | VAF 32/86 reads (37%) | catalogued as COSV60653053; called by muse, mutect2, varscan2
- SLC4A9 | c.436C>T p.P146S (on ENST00000507527 / NM_001258428.2; = p.P122S on NM_031467.3) | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.031); catalogued as COSV50192428; called by muse, mutect2, varscan2
- SMARCA4 | c.3203G>T p.G1068V | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV60786283, COSV60795540; called by muse, mutect2, varscan2
- SP140L | c.1090C>A p.L364I | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV54744461; called by muse, mutect2, varscan2
- SYT4 | c.47C>T p.T16I | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV54900734; called by muse, mutect2
- TCTA | c.30G>T p.L10F | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.119); catalogued as COSV55534073; called by muse, mutect2, varscan2
- TCTA | c.31C>T p.Q11* | Nonsense Mutation (SNP) | VAF 11/48 reads (23%) | catalogued as rs1447266953, COSV99648785; called by muse, mutect2, varscan2
- THADA | c.154A>G p.I52V | Missense Mutation (SNP) | VAF 60/120 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV67090269; called by muse, mutect2, varscan2
- TMEM33 | c.614+1G>T p.X205_splice | Splice Site (SNP) | VAF 11/24 reads (46%) | catalogued as COSV52562029, COSV52562475; called by muse, mutect2, varscan2
- TMPRSS7 | c.1337A>T p.Q446L (on ENST00000452346; = p.Q320L on NM_001042575.2) | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as COSV69980828; called by muse, mutect2, varscan2
- TRPM4 | c.1538A>T p.K513M | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV53263269; called by muse, mutect2, varscan2
- UBE3C | c.778G>C p.V260L | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV61953444; called by muse, mutect2, varscan2
- UTP20 | c.5661A>C p.E1887D | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs1392984466, COSV55377973; called by muse, mutect2, varscan2
- VPS13A | c.7969C>G p.H2657D | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV62430677; called by muse, mutect2, varscan2
- XIRP2 | c.7907A>T p.D2636V (on ENST00000628543; = p.D2811V on NM_152381.6) | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV54703139; called by muse, mutect2, varscan2
- ZBTB43 | c.404A>G p.N135S | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.82); PolyPhen benign (0.063); catalogued as COSV65094796; called by muse, mutect2, varscan2
- ZC3H15 | c.32G>A p.G11D | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.106); catalogued as rs1440954631, COSV61922412; called by muse, mutect2, varscan2
- ZFHX3 | c.3197C>G p.A1066G | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV51720018; called by muse, mutect2, varscan2
- ZKSCAN8 | c.1597C>G p.L533V | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57638463; called by muse, mutect2, varscan2
- ZMIZ2 | c.823G>A p.G275R | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV54808547; called by muse, mutect2, varscan2
- ZNF468 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs772352377, COSV54694894; called by muse, mutect2, varscan2
- ZNF586 | c.689G>T p.G230V | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1403456500, COSV66972391; called by muse, mutect2, varscan2
- ZNF831 | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV64040730, COSV64042172; called by muse, mutect2, varscan2
- ZSCAN25 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs762255222, COSV53553163; called by muse, mutect2, varscan2
- ATF5 | c.640_641del p.K214Efs*20 | Frame Shift Del (DEL) | VAF 58/116 reads (50%) | called by mutect2, pindel, varscan2
- BRWD3 | c.4415_4427del p.K1472Sfs*134 | Frame Shift Del (DEL) | VAF 19/81 reads (23%) | called by mutect2, pindel, varscan2
- DNAJB14 | c.1107dup p.E370Rfs*8 | Frame Shift Ins (INS) | VAF 86/251 reads (34%) | called by mutect2, pindel, varscan2
- ENAH | c.684_687del p.E228Dfs*23 | Frame Shift Del (DEL) | VAF 20/75 reads (27%) | called by pindel, varscan2
- HEY2 | c.762del p.T255Pfs*92 | Frame Shift Del (DEL) | VAF 4/43 reads (9%) | called by mutect2, pindel
- KRTDAP | c.283del p.T95Lfs*17 | Frame Shift Del (DEL) | VAF 16/81 reads (20%) | called by mutect2, pindel, varscan2
- MAG | c.1368_1377del p.E457Sfs*50 | Frame Shift Del (DEL) | VAF 22/51 reads (43%) | called by mutect2, pindel, varscan2
- MUC2 | c.1446dup p.G483Rfs*4 | Frame Shift Ins (INS) | VAF 17/40 reads (43%) | called by mutect2, pindel, varscan2
- PLXNB2 | c.2893_2905del p.Y965Pfs*42 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | called by mutect2, pindel, varscan2
- PRAMEF15 | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 16/170 reads (9%) | called by muse, mutect2
- RBBP6 | c.4794dup p.E1599* | Frame Shift Ins (INS) | VAF 28/150 reads (19%) | called by mutect2, pindel, varscan2
- RNF148 | c.185_198del p.F62Sfs*13 | Frame Shift Del (DEL) | VAF 24/115 reads (21%) | called by mutect2, pindel, varscan2
- THAP10 | c.562del p.R188Vfs*11 | Frame Shift Del (DEL) | VAF 66/243 reads (27%) | called by mutect2, pindel, varscan2
- TMCO3 | c.1718_1720delinsAA p.A573Efs*16 | Frame Shift Del (DEL) | VAF 16/73 reads (22%) | called by pindel, varscan2*
- TPM2 | c.330_336del p.Q111Wfs*15 | Frame Shift Del (DEL) | VAF 19/46 reads (41%) | called by mutect2, pindel, varscan2
- TRAK1 | c.1473_1476delinsTAA p.S492Nfs*8 (on ENST00000327628 / NM_001349247.2; = p.S434Nfs*8 on NM_014965.5) | Frame Shift Del (DEL) | VAF 27/197 reads (14%) | called by pindel, varscan2*
- ZNF257 | c.588_589del p.I196Mfs*8 | Frame Shift Del (DEL) | VAF 14/41 reads (34%) | called by mutect2, varscan2
- ZNF280C | c.1568dup p.L523Ffs*28 | Frame Shift Ins (INS) | VAF 23/62 reads (37%) | called by mutect2, pindel, varscan2
- ZXDC | c.677dup p.R227Afs*28 | Frame Shift Ins (INS) | VAF 32/214 reads (15%) | called by mutect2, pindel, varscan2
- ATG2B | c.3630C>T p.S1210= | Silent (SNP) | VAF 18/138 reads (13%) | catalogued as COSV55890505; called by muse, mutect2, varscan2
- CA8 | c.672C>A p.I224= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as COSV58772148; called by muse, mutect2, varscan2
- CEP104 | c.2388G>C p.T796= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV65517592, COSV65519086; called by muse, mutect2, varscan2
- COLEC12 | c.1773C>T p.P591= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as COSV68370869; called by muse, mutect2, varscan2
- DCAKD | c.633A>G p.T211= | Silent (SNP) | VAF 27/32 reads (84%) | catalogued as COSV60831188; called by muse, mutect2, varscan2
- DENND4A | c.762A>G p.V254= | Silent (SNP) | VAF 52/180 reads (29%) | catalogued as COSV71265913; called by muse, mutect2, varscan2
- DYNC2H1 | c.252A>G p.E84= | Silent (SNP) | VAF 9/223 reads (4%) | catalogued as COSV62095003; called by muse, mutect2
- EGF | c.2931C>T p.P977= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs1251629116, COSV54479438; called by muse, mutect2, varscan2
- EPHA7 | c.1893C>T p.S631= | Silent (SNP) | VAF 60/88 reads (68%) | catalogued as COSV100994486, COSV65183507; called by muse, mutect2, varscan2
- FAT2 | c.5502C>A p.P1834= | Silent (SNP) | VAF 24/122 reads (20%) | catalogued as COSV55820481; called by muse, mutect2, varscan2
- FBN2 | c.2166A>G p.A722= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as rs1425557353, COSV52515904; called by muse, mutect2, varscan2
- FILIP1L | c.3249T>C p.P1083= (on ENST00000354552 / NM_182909.3; = p.P843= on NM_014890.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/214 reads (16%) | catalogued as COSV100497406; called by muse, mutect2, varscan2
- GPR158 | c.642C>T p.A214= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as rs1378623436, COSV66271069; called by muse, varscan2
- GPRIN1 | c.1248G>A p.V416= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as COSV56139389, COSV99991421; called by muse, mutect2, varscan2
- HBP1 | c.126A>G p.P42= | Silent (SNP) | VAF 29/114 reads (25%) | catalogued as rs772877520, COSV56016889; called by muse, mutect2, varscan2
- HYOU1 | c.1257A>T p.A419= | Silent (SNP) | VAF 32/100 reads (32%) | catalogued as COSV68215874; called by muse, mutect2, varscan2
- IFNA8 | c.207A>G p.K69= | Silent (SNP) | VAF 36/71 reads (51%) | catalogued as COSV66504626, COSV66504967; called by muse, mutect2, varscan2
- IL4R | c.1890G>T p.G630= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV50145475; called by muse, mutect2, varscan2
- KIF26B | c.3345T>C p.S1115= | Silent (SNP) | VAF 27/95 reads (28%) | catalogued as COSV63642322; called by muse, mutect2, varscan2
- KRT83 | c.102C>G p.A34= | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as COSV99531929; called by muse, mutect2, varscan2
- LGALS9 | c.606C>T p.S202= (on ENST00000395473 / NM_009587.3; = p.S170= on NM_002308.4) | Silent (SNP) | VAF 107/203 reads (53%) | catalogued as rs1201505424, COSV56349052; called by muse, mutect2, varscan2
- LOXL4 | c.1971A>T p.A657= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV53256910; called by muse, mutect2
- MAGEL2 | c.2472C>T p.P824= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as COSV100045990, COSV58567351; called by muse, mutect2, varscan2
- MUC5B | c.756C>A p.A252= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs781163769, COSV71592166; called by muse, mutect2, varscan2
- NCAPH2 | c.1579C>A p.R527= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV52688003; called by muse, mutect2, varscan2
- NEK3 | c.846A>G p.K282= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as COSV51617151; called by muse, mutect2, varscan2
- NMNAT3 | c.240G>A p.V80= (on ENST00000296202 / NM_001320512.1; = p.V43= on NM_178177.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as COSV56156465; called by muse, mutect2, varscan2
- NOVA1 | c.363A>C p.R121= | Silent (SNP) | VAF 29/80 reads (36%) | catalogued as COSV57477688; called by muse, mutect2, varscan2
- NYAP1 | c.468C>T p.S156= | Silent (SNP) | VAF 41/186 reads (22%) | catalogued as rs372170892, COSV55719481; called by muse, mutect2, varscan2
- OSBPL2 | c.75G>A p.E25= (on ENST00000313733 / NM_144498.4; = p.E13= on NM_014835.4) | Silent (SNP) | VAF 9/102 reads (9%) | catalogued as COSV58216897; called by muse, mutect2
- PCDH1 | c.867A>G p.L289= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as COSV54614371; called by muse, mutect2, varscan2
- PCK2 | c.1381C>T p.L461= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV53749040, COSV99394366; called by muse, mutect2
- PIK3C2B | c.1353C>G p.R451= | Silent (SNP) | VAF 9/143 reads (6%) | catalogued as COSV65803682; called by muse, mutect2
- PRDM15 | c.1575G>T p.T525= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV54153374; called by muse, mutect2, varscan2
- PRKAG2 | c.1698A>G p.T566= | Silent (SNP) | VAF 34/167 reads (20%) | catalogued as COSV55229978; called by muse, mutect2, varscan2
- PRR12 | c.3027C>T p.S1009= (on ENST00000615927; = p.S1830= on NM_020719.3) | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as rs200097233; called by muse, mutect2, varscan2
- RAB25 | c.480C>G p.T160= | Silent (SNP) | VAF 45/176 reads (26%) | catalogued as COSV63108133; called by muse, mutect2, varscan2
- RASAL2 | c.2496A>G p.E832= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV62714598; called by muse, mutect2, varscan2
- SACS | c.12960T>C p.L4320= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as COSV66540483; called by muse, mutect2, varscan2
- SAMD1 | c.1113G>A p.P371= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as rs1434862178, COSV54114612; called by muse, mutect2, varscan2
- SCUBE1 | c.2133G>A p.E711= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs1371537181, COSV62612741; called by muse, mutect2, varscan2
- SLCO4A1 | c.6C>G p.P2= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV53891154; called by muse, mutect2, varscan2
- STAB2 | c.5886C>T p.C1962= | Silent (SNP) | VAF 26/65 reads (40%) | catalogued as rs747762448, COSV66339600; called by muse, mutect2, varscan2
- TNRC6C | c.1551G>A p.V517= | Silent (SNP) | VAF 27/50 reads (54%) | catalogued as rs566391812, COSV56945760; called by muse, mutect2, varscan2
- TPO | c.1002G>T p.P334= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as COSV61099582, COSV61102669; called by muse, mutect2
- TPRG1L | c.459A>G p.K153= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV54561233; called by muse, mutect2, varscan2
- TRAF6 | c.1533G>A p.E511= | Silent (SNP) | VAF 29/92 reads (32%) | catalogued as COSV61922602; called by muse, mutect2, varscan2
- YEATS2 | c.1881C>A p.S627= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV59364962, COSV59366169; called by muse, mutect2, varscan2
- ZMIZ1 | c.603G>A p.A201= | Silent (SNP) | VAF 64/154 reads (42%) | catalogued as rs745339623, COSV100566045, COSV57899805; called by muse, mutect2, varscan2
- ANK1 | c.5619+1317G>C | Intron (SNP) | VAF 6/66 reads (9%) | catalogued as COSV99226987; called by muse, mutect2
- CHL1 | c.679+904A>G | Intron (SNP) | VAF 54/195 reads (28%) | catalogued as COSV56594456; called by muse, varscan2
- HSP90AB1 | c.*118T>C | 3'UTR (SNP) | VAF 67/139 reads (48%) | catalogued as rs567895542, COSV51488250, COSV99241449; called by muse, mutect2, varscan2
- POM121 | chr7:72949051 A>T | 3'Flank (SNP) | VAF 33/136 reads (24%) | catalogued as COSV57516498; called by muse, mutect2, varscan2
- RPL13A | c.257-92C>T | Intron (SNP) | VAF 25/88 reads (28%) | catalogued as COSV99201361; called by muse, mutect2, varscan2
